Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4916, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4916-01A (Primary Tumor).

Surgery Date: [REDACTED]

TCGA-CJ-4916

Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY:

RENAL CELL CARCINOMA:

- CONVENTIONAL (CLEAR CELL) TYPE,
- FUHRMAN NUCLEAR GRADE 3,
- 10.4 X 7.0 X 5.0 CM,
- INVADING THE RENAL VEIN.

Resection margins (renal vein, renal artery, ureter and perirenal soft tissue), no tumor present.

(B) RIGHT ADRENAL GLAND:

Adrenal gland, no tumor present.

GROSS DESCRIPTION

(A) RIGHT KIDNEY - A radical nephrectomy specimen (24.0 x 13.0 x 6.5 cm), includes: the right kidney (15.5 x 8.5 x 5.0 cm), a segment of the renal artery, the renal vein, and ureter (14.0 cm in length and 0.2 cm average diameter). The adrenal gland is not present with the specimen.

There is a 10.4 x 7.0 x 5.0 cm well-circumscribed tumor in the lower pole of the kidney. The tumor is yellow with focal areas of hemorrhage and myxoid change. No distinct necrosis is identified. The tumor does not appear to invade the renal sinus, renal pelvis or the perinephric adipose tissue. The tumor extends to the renal vein but it does not involve the renal vein margin. The tumor does not extend to Gerota's fascia.

The adjacent kidney parenchyma is unremarkable. The pelvicalyceal system is smooth and devoid of lesions. No lymph nodes are identified in the hilum of the kidney.

Portions of the kidney are submitted for electron microscopy (on hold). Portions of the tumor and normal kidney are submitted in a sterile fashion for research purposes.

INK CODE:

Black - Gerota's fascia.

SECTION CODE:

- A01, ureter and renal vein margin;
- A02, renal vein thrombus;
- A03, A04, normal appearing kidney;
- A05, A06, tumor with relationship to renal pelvis;
- A07, A08, tumor with relationship to Gerota's fascia;
- A09-A13, representative sections of tumor [REDACTED]

(B) RIGHT ADRENAL - An adrenal gland with surrounding fat (10.5 x 4.0 x 2.0 cm). The adrenal gland measures 4.5 x 3.5 x 1.7 and weighs 15.0 grams. Serial sectioning revealed grossly unremarkable adrenal cortex and medulla. Representative sections are submitted in three cassettes (80% of the adrenal gland). [REDACTED]

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, M-83123

Source: NCI Genomic Data Commons file f1386329-6661-4083-826a-9af750c5a8e2 (TCGA-CJ-4916.E6B50A2A-5711-4ED3-BA35-9CFC5FA5283A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).